Somatic mutation profile of tumor specimen TCGA-CS-5393-01A (aliquot TCGA-CS-5393-01A-01D-1468-08) from TCGA case TCGA-CS-5393, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 39.5 years (14,418 days).
Specimen TCGA-CS-5393-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffc2a3f8-0a58-4fdc-adf0-706a5612a56b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-5393-10A (Blood Derived Normal), aliquot TCGA-CS-5393-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d475f13-fb08-4ee2-b977-fefdd1fdff07

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 35/116 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 45/63 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064794311, CM973401, COSV52661102, COSV52687307, COSV99402633; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB4 | c.2482A>G p.T828A | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.052); catalogued as COSV55934716; called by muse, mutect2, varscan2
- BCL6 | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51651717; called by muse, mutect2, varscan2
- CCDC82 | c.1448T>A p.F483Y | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV53593244; called by muse, mutect2, varscan2
- CSMD3 | c.8770C>T p.P2924S (on ENST00000297405 / NM_001363185.1; = p.P2755S on NM_052900.3) | Missense Mutation (SNP) | VAF 70/351 reads (20%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.61); catalogued as COSV52155351, COSV52167751; called by muse, mutect2, varscan2
- KRT6C | c.926T>C p.M309T | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as rs765896990, COSV52877516, COSV52880715; called by muse, mutect2, varscan2
- NEB | c.10265G>A p.R3422H | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs755314719, COSV51271396; called by muse, mutect2, varscan2
- OR2W3 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64456756, COSV64458134; called by muse, mutect2, varscan2
- OR51F2 | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.196); catalogued as COSV59064580; called by muse, mutect2, varscan2
- OR8B4 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs778949684, COSV62069649; called by muse, mutect2, varscan2
- PRDM9 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs1425057806, COSV57002819, COSV57012319; called by muse, mutect2, varscan2
- RTL9 | c.571T>C p.S191P | Missense Mutation (SNP) | VAF 75/127 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV71825521; called by muse, mutect2, varscan2
- SMARCA4 | c.2651A>G p.H884R | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV60793246, COSV60804891; called by muse, mutect2, varscan2
- TNXB | c.5722G>A p.A1908T (on ENST00000647633; = p.A1661T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV64478279; called by muse, mutect2, varscan2
- UBR3 | c.4931A>G p.K1644R | Missense Mutation (SNP) | VAF 118/315 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV55848610; called by muse, mutect2, varscan2
- URI1 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as rs140683632, COSV100368949; called by muse, mutect2, varscan2
- WDFY3 | c.9952G>A p.A3318T | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs753138565, COSV55699883, COSV55714175; called by muse, mutect2, varscan2
- ZMIZ2 | c.2195C>A p.P732H | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs761539768, COSV54807674; called by muse, varscan2
- FAM118B | c.798C>G p.V266= | Silent (SNP) | VAF 46/107 reads (43%) | catalogued as COSV64156986; called by muse, mutect2, varscan2
- GDAP2 | c.747G>T p.V249= | Silent (SNP) | VAF 69/213 reads (32%) | catalogued as COSV65612392; called by muse, mutect2, varscan2
- PLEKHA8 | c.705C>T p.I235= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as COSV51650823; called by muse, mutect2, varscan2
- PYROXD1 | c.123A>G p.V41= | Silent (SNP) | VAF 12/196 reads (6%) | catalogued as COSV53709427; called by muse, mutect2
- RAPGEF2 | c.4278G>A p.P1426= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs374199273; called by muse, varscan2
- SPTBN1 | c.5775C>G p.L1925= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV61688170; called by muse, mutect2, varscan2
- THBS1 | c.2265A>G p.P755= | Silent (SNP) | VAF 71/213 reads (33%) | catalogued as rs1379662884, COSV52951664; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83305C>T | Intron (SNP) | VAF 12/320 reads (4%) | called by muse, mutect2
